Gene-level copy-number profile of tumor specimen HCM-SANG-0518-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-0518-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0518-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f193ab3b-531c-4da6-920a-9b974543ffd9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0518-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/034ce1a6-645f-40a5-bcd8-9a1880b44e8c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 522; copy number 1: 3,909; copy number 2: 50,117; copy number 3: 2,979; copy number 4: 1,381; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,175,528–4,424,689, 2 genes: EEF1DP6, LINC01777.
- chr9:61,581,813–61,642,494, 3 genes: AL935212.3, FAM242D, Y_RNA.
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–1): RNU6-457P.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–4): RPS10P2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–4): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:65,287,914–65,734,041, 4 genes, copy number 5: CBWD4P, Y_RNA, FRG1KP, CBWD5.

Autosomal genes at a single copy (total copy number 1): 3,903. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
